Gene-level copy-number profile of tumor specimen MP2PRT-PARCIY-TBP1-A from MP2PRT case MP2PRT-PARCIY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,254 days).
Specimen MP2PRT-PARCIY-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4812593c-1ffd-472a-8e77-3e117828b7f2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARCIY-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/8d868377-d684-4ed7-9284-60c7e1791051

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 128; copy number 1: 544; copy number 2: 30,393; copy number 3: 3,323; copy number 4: 22,597; copy number 5: 55; copy number 6: 1,866; copy number 32: 3.

Homozygous deletions (total copy number 0; autosomes only): 128 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,672,308–106,481,706, 126 genes (within-gene range 0–4) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–4): IGHVIII-47-1, IGHV3-48.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,924 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:137,682–157,887, 3 genes, copy number 32: AL627309.7, AL627309.2, RNU6-1100P.
- chr18:45,034–80,247,514, 1,199 genes, copy number 5–6 (broad region; genes not listed).
- chr21:13,038,160–46,691,226, 722 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 32. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
